Gene-level copy-number profile of tumor specimen TCGA-18-4083-01A from TCGA case TCGA-18-4083, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.3 years (23,125 days).
Specimen TCGA-18-4083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.61c824af-6ea9-4387-983b-98a5d9b7e4c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-4083-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce50bcc4-dcc9-4535-aef9-33346fcf21aa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 2,006; copy number 2: 20,714; copy number 3: 24,685; copy number 4: 8,160; copy number 5: 1,935; copy number 6: 214; copy number 7: 1,116; copy number 8: 371; copy number 9: 372; copy number 10: 86; copy number 12: 4; copy number 20: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-4083-01A-01D-1097-01): tumor purity 0.68, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,460,926–25,844,585, 96 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,962 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:201,487,421–206,420,238, 116 genes, copy number 9 (within-gene range 1–9) (broad region; genes not listed).
- chr3:161,600,438–198,222,513, 647 genes, copy number 7–9 (broad region; genes not listed).
- chr5:13,690,331–19,142,346, 100 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:21,341,833–36,725,195, 201 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr5:39,284,140–44,828,592, 94 genes, copy number 7 (broad region; genes not listed).
- chr7:20,330,702–21,945,903, 19 genes, copy number 8 (within-gene range 3–8): ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L.
- chr12:111,642,146–120,594,548, 207 genes, copy number 7–20 (within-gene range 4–20) (broad region; genes not listed).
- chr13:73,399,031–73,661,891, 4 genes, copy number 12 (within-gene range 3–12): AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr18:29,518,259–69,849,087, 551 genes, copy number 7 (broad region; genes not listed).
- chr21:17,210,469–18,486,599, 23 genes, copy number 7: NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1.

Autosomal genes at a single copy (total copy number 1): 1,999. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
